Gene-level copy-number profile of tumor specimen BLGSP-71-23-00446-01A from CGCI case BLGSP-71-23-00446, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 26.2 years (9,569 days).
Specimen BLGSP-71-23-00446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 646d766f-cc91-4803-80fe-12fc70d93d51.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-23-00446-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/ce474ce3-a84d-4334-b8f4-944e1240734b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,220; copy number 2: 53,911; copy number 3: 1,673; copy number 4: 59; copy number 5: 11; copy number 7: 1; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:9,153,296–9,176,730, 3 genes: FAM86KP, ALG1L14P, FAM90A26.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,359,809–90,367,699, 2 genes, copy number 5: AC233263.1, AC233263.7.
- chr3:196,452,996–196,453,055, 1 gene, copy number 5: AC117490.1.
- chr7:74,796,144–74,851,551, 1 gene, copy number 5: GTF2IRD2.
- chr7:75,391,955–75,395,434, 1 gene, copy number 7 (within-gene range 3–7): AC211486.1.
- chr9:66,721,158–66,745,929, 3 genes, copy number 9: ATP5F1AP10, SDR42E1P4, FKBP4P8.
- chr14:18,333,726–18,412,264, 3 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2.
- chr15:43,599,563–43,618,800, 1 gene, copy number 5 (within-gene range 2–5): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 5 (within-gene range 2–5): AC011330.3.
- chr16:32,600,299–32,615,639, 1 gene, copy number 5: AC137800.1.
- chr16:32,635,673–32,636,045, 1 gene, copy number 5: AC133569.1.

Autosomal genes at a single copy (total copy number 1): 370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
